Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A0TP, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A0TP-01A (Primary Tumor).

ICD-0-3

Carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9

Breast, left, wide local excision: Infiltrating ductal carcinoma, Nottingham grade III (of III) forming a 3 x 3 x 2.5 cm mass. Less than 10% of the tumor is in situ. No vascular invasion is identified. (AJCC pT2)
The margins of excision are free of tumor.

Lymph nodes, left axillary sentinel No.1 and No.2, excision: Multiple (2) left axillary sentinel lymph nodes are negative for tumor, and contain no blue dye. Cytokeratin immunostains performed on both sentinel lymph nodes confirm the H&E impression (AJCC pN0(i-)).

Lymph nodes, left axillary, excision: Multiple (3) left axillary lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file e6d9087e-1fe1-44e7-8e68-1458a692e8dd (TCGA-AR-A0TP.E1A92F92-1DD2-4E33-9C16-3FD0371D1431.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).